Gene-level copy-number profile of tumor specimen TCGA-29-1783-01A from TCGA case TCGA-29-1783, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.3 years (21,284 days).
Specimen TCGA-29-1783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.394c6744-3478-4a86-939d-34ec5641067b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1783-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ed50d8f0-566e-47f9-ade7-e695bdc862f4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 944; copy number 2: 18,212; copy number 3: 20,266; copy number 4: 13,660; copy number 5: 4,379; copy number 6: 1,194; copy number 7: 520; copy number 8: 216; copy number 9: 8; copy number 10: 380; copy number 12: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1783-01A-01D-0559-01): tumor purity 0.71, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,732 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:54,099,968–55,215,364, 34 genes, copy number 5: AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL, MRPL37, SSBP3, SSBP3-AS1, AL161644.1, AL035415.1, AC099796.2, LINC02784, AC099796.1, HNRNPA1P63, ACOT11, FAM151A, AL590093.1, MROH7, MROH7-TTC4, TTC4, PARS2, TTC22, AC096536.1, LEXM, DHCR24, AC096536.3, AC096536.2, DHCR24-DT, AL590440.2, TMEM61, AL590440.1, BSND, PCSK9, USP24.
- chr1:55,222,379–55,225,723, 2 genes, copy number 5: GYG1P3, MIR4422.
- chr1:106,544,342–168,376,876, 1,358 genes, copy number 5 (broad region; genes not listed).
- chr1:169,849,631–186,988,981, 331 genes, copy number 5–6 (broad region; genes not listed).
- chr1:190,878,145–191,151,410, 1 gene, copy number 7 (within-gene range 4–7): AL138927.1.
- chr1:217,631,324–239,915,452, 489 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:53,849,122–54,383,742, 11 genes, copy number 5: MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73.
- chr8:46,028,804–57,244,793, 174 genes, copy number 5–7 (broad region; genes not listed).
- chr8:131,129,761–138,083,657, 73 genes, copy number 6–8 (broad region; genes not listed).
- chr11:43,556,436–43,673,393, 1 gene, copy number 7 (within-gene range 4–7): AC068205.1.
- chr11:43,578,889–43,840,030, 1 gene, copy number 7 (within-gene range 4–7): AC068205.2.
- chr11:43,680,680–44,310,139, 18 genes, copy number 7 (within-gene range 4–7): HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4, ALKBH3, SEC14L1P1, ALKBH3-AS1, AC087521.3, C11orf96, AC087521.1, ACCSL, ACCS, AC134775.1, EXT2, ALX4.
- chr11:102,229,851–102,836,766, 23 genes, copy number 5 (within-gene range 4–5): AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2.
- chr12:6,409,637–32,107,528, 660 genes, copy number 5–6 (broad region; genes not listed).
- chr12:32,109,076–32,228,154, 2 genes, copy number 5: AC048344.4, AC016954.1.
- chr13:21,671,073–114,337,626, 1,281 genes, copy number 5 (broad region; genes not listed).
- chr19:7,005,012–22,784,151, 863 genes, copy number 5–12 (within-gene range 4–12) (broad region; genes not listed).
- chr19:27,638,483–30,228,715, 63 genes, copy number 5 (broad region; genes not listed).
- chr19:30,907,199–35,169,881, 126 genes, copy number 6–8 (broad region; genes not listed).
- chr19:48,047,843–48,614,854, 28 genes, copy number 7: PLA2G4C, PLA2G4C-AS1, LIG1, AC011466.3, AC011466.2, ZSWIM9, CARD8, AC011466.4, AC011466.1, CARD8-AS1, ZNF114-AS1, ZNF114, CCDC114, EMP3, TMEM143, SYNGR4, KDELR1, GRIN2D, GRWD1, KCNJ14, AC008403.2, AC008403.1, CYTH2, LMTK3, AC008403.3, SULT2B1, FAM83E, SPACA4.
- chr20:87,250–54,651,169, 1,193 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 944. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
